Somatic mutation profile of tumor specimen a467b905-fc0b-427b-8753-6d38dd (aliquot a467b905-fc0b-427b-8753-6d38dd_D6) from CPTAC case 21CO007, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV.
Specimen a467b905-fc0b-427b-8753-6d38dd: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72929fe5-76da-457c-bf1c-a46d50628c25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 8f5bf7df-cd1f-4300-a6c2-1aa47c (Blood Derived Normal), aliquot 8f5bf7df-cd1f-4300-a6c2-1aa47c_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75e1ac27-3e4f-4e9d-ac25-ff478b2feb29

The open-access MAF lists 154 somatic variants for this specimen: 118 protein-altering or splice-affecting, 20 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 20, Intron 9, Nonsense Mutation 7, Frame Shift Del 4, 5'UTR 3, 3'UTR 2, RNA 2, Splice Region 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 240/416 reads (58%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 174/356 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NSD1 | c.5332C>T p.R1778* | Nonsense Mutation (SNP) | VAF 109/393 reads (28%) | catalogued as rs794727176, CM030076, COSV61785134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASS | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 37/179 reads (21%) | catalogued as COSV62788623; called by muse, mutect2, varscan2
- ABCA9 | c.3460A>G p.T1154A | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs754565719; called by muse, mutect2, varscan2
- ACVR1C | c.326T>G p.L109R | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.541); catalogued as COSV99694316, COSV99694363; called by muse, mutect2, varscan2
- AHDC1 | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs750185125, COSV99899904; called by muse, mutect2, varscan2
- ARNTL2 | c.1757G>T p.S586I | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs773931724; called by muse, mutect2, varscan2
- BIRC6 | c.11231C>T p.S3744F | Missense Mutation (SNP) | VAF 87/368 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs751043719, COSV101428051; called by muse, mutect2, varscan2
- CACHD1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs760611986, COSV51548629; called by muse, mutect2, varscan2
- CACNA1C | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 63/319 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.585); catalogued as rs760888275, COSV99046824; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CDH23 | c.6910C>T p.R2304W | Missense Mutation (SNP) | VAF 78/300 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1265719839, COSV56457415; called by muse, mutect2, varscan2
- CFAP46 | c.4787C>T p.T1596M | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs1255849886; called by muse, mutect2, varscan2
- CHP2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs756478431, COSV55649342; called by muse, mutect2, varscan2
- DDX53 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV60069795; called by muse, mutect2, varscan2
- DHX16 | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762169796; called by muse, mutect2, varscan2
- DMD | c.9569G>A p.R3190Q | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766768395, COSV58939355; ClinVar: uncertain significance; called by muse, varscan2
- DZIP1 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV61265483; called by muse, mutect2, varscan2
- EEF1AKNMT | c.746G>A p.R249Q (on ENST00000361735 / NM_015935.5; = p.R163Q on NM_014955.3) | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.153); catalogued as rs781641502; called by muse, mutect2, varscan2
- ELFN1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 45/290 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.199); catalogued as rs1217296779; called by muse, mutect2, varscan2
- ESPNL | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.828); catalogued as rs144639872; called by muse, mutect2, varscan2
- GAB3 | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs781853785, COSV65820194; called by muse, mutect2, varscan2
- HDX | c.1458G>A p.W486* | Nonsense Mutation (SNP) | VAF 30/98 reads (31%) | catalogued as rs1569284670; called by muse, mutect2, varscan2
- HMCN1 | c.227G>T p.R76I | Missense Mutation (SNP) | VAF 46/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs759967411, COSV54878387, COSV54946316; called by muse, mutect2, varscan2
- IGLV1-47 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as rs1435157092; called by muse, mutect2, varscan2
- IL16 | c.349A>G p.K117E | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV57269115; called by muse, mutect2, varscan2
- KIF19 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 79/129 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760396711; called by muse, mutect2, varscan2
- KLHL5 | c.649A>G p.K217E | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV54671947; called by muse, mutect2, varscan2
- LGSN | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as rs775519999, COSV65726818; called by muse, mutect2, varscan2
- LRP12 | c.1123del p.C375Vfs*113 | Frame Shift Del (DEL) | VAF 106/295 reads (36%) | catalogued as COSV99407667; called by mutect2, pindel, varscan2
- NID1 | c.2754G>A p.P918= | Splice Region (SNP) | VAF 34/152 reads (22%) | catalogued as COSV51614210; called by muse, mutect2, varscan2
- PGM2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as rs373814980; called by muse, mutect2, varscan2
- PNMA5 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs782553555, COSV62625985; called by muse, mutect2, varscan2
- PRKCE | c.2110C>T p.R704W | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1250265961, COSV100078913; called by muse, mutect2, varscan2
- PSME4 | c.824A>G p.Y275C | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs982754482, COSV66365364; called by muse, mutect2, varscan2
- RAB11FIP3 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 50/289 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.628); catalogued as rs775060385, COSV51934944; called by muse, mutect2, varscan2
- RAB38 | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.458); catalogued as COSV99702989; called by muse, mutect2, varscan2
- RGS20 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.043); catalogued as rs1435871455, COSV52017447; called by muse, mutect2, varscan2
- RP1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 192/447 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55118474; called by mutect2, varscan2
- RPL27 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.063); catalogued as rs776186138, COSV53814748; called by muse, mutect2, varscan2
- SLC30A5 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV67449625; called by muse, mutect2
- STIM1 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 84/358 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs555016539, COSV56153429; called by muse, mutect2, varscan2
- TARBP1 | c.2566G>A p.A856T | Missense Mutation (SNP) | VAF 62/285 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs149931337, COSV50194129; called by muse, mutect2, varscan2
- TFRC | c.1795A>G p.I599V | Missense Mutation (SNP) | VAF 87/405 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs377249426; called by muse, mutect2, varscan2
- THBS4 | c.1858C>A p.L620M | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63470701; called by mutect2, varscan2
- TRHDE | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 60/166 reads (36%) | catalogued as COSV53839468; called by muse, mutect2, varscan2
- UGGT2 | c.4194G>C p.K1398N | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100948512; called by muse, mutect2, varscan2
- VIPR2 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150965113; called by muse, mutect2, varscan2
- VWF | c.5155T>C p.S1719P | Missense Mutation (SNP) | VAF 143/608 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV54620215; called by muse, mutect2, varscan2
- WIF1 | c.259A>G p.M87V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs762416182; called by muse, mutect2, varscan2
- ZFR2 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as rs767773243; called by muse, mutect2, varscan2
- ZNF420 | c.1755A>T p.K585N | Missense Mutation (SNP) | VAF 61/282 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV58494687; called by mutect2, varscan2
- ZNF429 | c.575A>C p.K192T | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV61916642; called by muse, mutect2, varscan2
- ZNF606 | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778669433; called by muse, mutect2, varscan2
- ZNF713 | c.898C>A p.P300T (on ENST00000633730 / NM_001366796.2; = p.P313T on NM_182633.3) | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770895448; called by muse, mutect2, varscan2
- ZNF836 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.903); catalogued as rs529214922, COSV59081864; called by muse, mutect2, varscan2
- ZNF99 | c.797T>C p.F266S | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746509555; called by muse, mutect2, varscan2
- A2M | c.3896del p.L1299Yfs*16 | Frame Shift Del (DEL) | VAF 61/513 reads (12%) | called by mutect2, pindel, varscan2
- ABCC4 | c.3514G>T p.E1172* | Nonsense Mutation (SNP) | VAF 36/218 reads (17%) | called by muse, mutect2, varscan2
- ANKRD36B | c.2894_2895del p.T965Nfs*15 | Frame Shift Del (DEL) | VAF 37/314 reads (12%) | called by pindel, varscan2
- APBA1 | c.322C>G p.R108G | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CEP135 | c.1771A>C p.K591Q | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- CNTNAP2 | c.1541A>T p.Q514L | Missense Mutation (SNP) | VAF 99/416 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CORIN | c.2367C>A p.D789E | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CRYBA2 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DIAPH3 | c.1751G>T p.G584V (on ENST00000400324 / NM_001042517.2; = p.G321V on NM_030932.3) | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DOCK7 | c.525C>G p.D175E | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- DOCK9 | c.5428G>T p.D1810Y (on ENST00000376460 / NM_001366676.2; = p.D1811Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM133A | c.290G>T p.R97I | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- FAM98B | c.385A>T p.I129L | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- FBRSL1 | c.2428C>G p.L810V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- HIPK3 | c.1353G>T p.E451D | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ITPRIPL1 | c.574A>T p.S192C (on ENST00000439118 / NM_001008949.3; = p.S200C on NM_178495.6) | Missense Mutation (SNP) | VAF 82/391 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KANSL1L | c.2281C>T p.R761* | Nonsense Mutation (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
- KCTD8 | c.1390C>A p.Q464K | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLHL26 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 77/322 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.654); called by mutect2, varscan2
- LMNB1 | c.1077C>G p.D359E | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC14 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 114/778 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, varscan2
- MAN2A1 | c.3290T>C p.V1097A | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- MAST4 | c.518-1G>T p.X173_splice | Splice Site (SNP) | VAF 45/220 reads (20%) | called by muse, mutect2, varscan2
- MCC | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MMP16 | c.424A>G p.K142E | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MRPS30 | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- MTCL1 | c.5718G>T p.*1906Yext*? (on ENST00000306329 / NM_001378206.1; = p.*1587Yext*84 on NM_015210.4) | Nonstop Mutation (SNP) | VAF 46/147 reads (31%) | called by muse, mutect2, varscan2
- MXD4 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 75/313 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NABP1 | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLGN4X | c.506T>C p.M169T | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ONECUT2 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- OR11H4 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 121/185 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR6T1 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 109/511 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PACC1 | c.511G>C p.V171L | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHB13 | c.219A>T p.K73N | Missense Mutation (SNP) | VAF 58/317 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PELO | c.830C>G p.A277G | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- PREX2 | c.4205A>C p.K1402T | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- RANBP17 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.181); called by muse, mutect2
- RAPH1 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RC3H1 | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RNGTT | c.264del p.K88Nfs*35 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- SCN10A | c.4436A>G p.D1479G | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC13A1 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC2A2 | c.5C>G p.T2R | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SMG7 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPEM1 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- SYNJ2 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAS2R5 | c.572T>C p.L191P | Missense Mutation (SNP) | VAF 79/403 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D22A | c.1061A>G p.E354G | Missense Mutation (SNP) | VAF 86/400 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- TFAP2B | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 147/462 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TRBV23-1 | c.94A>C p.K32Q | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- TUB | c.1507C>G p.L503V (on ENST00000299506 / NM_177972.3; = p.L558V on NM_003320.4) | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- VWA5A | c.2293C>A p.P765T | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZBTB47 | c.1964C>T p.T655M | Missense Mutation (SNP) | VAF 116/211 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF329 | c.224C>A p.A75E | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- ZNF574 | c.1073A>G p.H358R | Missense Mutation (SNP) | VAF 97/378 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF726 | c.815T>C p.L272P | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF831 | c.4907T>A p.I1636K | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF878 | c.580T>C p.S194P | Missense Mutation (SNP) | VAF 98/456 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by mutect2, varscan2
- ZNF98 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by mutect2, varscan2
- ZNF99 | c.1668G>T p.K556N | Missense Mutation (SNP) | VAF 65/312 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ADGRB1 | c.4200C>T p.S1400= | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as rs1300039251; called by muse, varscan2
- ARHGEF7 | c.2160C>T p.Y720= (on ENST00000375741 / NM_001113511.2; = p.Y542= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 34/228 reads (15%) | called by muse, mutect2, varscan2
- ARMC9 | c.1197G>A p.A399= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as rs376296930; called by muse, mutect2, varscan2
- CBLC | c.1173C>T p.C391= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs781277300; called by muse, mutect2
- CHD5 | c.3009C>T p.A1003= | Silent (SNP) | VAF 62/204 reads (30%) | catalogued as rs780276723, COSV99315185; called by muse, mutect2, varscan2
- COX7C | c.63G>A p.E21= | Silent (SNP) | VAF 36/118 reads (31%) | called by mutect2, varscan2
- DERL3 | c.699G>A p.P233= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as rs993370589; called by muse, mutect2, varscan2
- DHRS7C | c.129C>T p.T43= | Silent (SNP) | VAF 90/164 reads (55%) | catalogued as rs375710874; called by muse, mutect2, varscan2
- DLGAP2 | c.1596C>T p.S532= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs758278309; called by muse, mutect2, varscan2
- IRAK3 | c.87C>T p.C29= | Silent (SNP) | VAF 49/166 reads (30%) | catalogued as rs1028762489; called by muse, mutect2, varscan2
- KRT27 | c.879C>T p.D293= | Silent (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- LRP2 | c.6537T>C p.T2179= | Silent (SNP) | VAF 42/133 reads (32%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1095C>T p.P365= | Silent (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- MUC5B | c.13164G>A p.T4388= | Silent (SNP) | VAF 166/750 reads (22%) | catalogued as rs370908099, COSV71594234; called by muse, mutect2, varscan2
- NFATC1 | c.2484G>A p.A828= (on ENST00000427363 / NM_001278669.2; = p.A815= on NM_172387.3) | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as rs1323320757; called by muse, mutect2, varscan2
- PKDREJ | c.891G>A p.S297= | Silent (SNP) | VAF 42/185 reads (23%) | called by muse, mutect2, varscan2
- PRKAB1 | c.807C>A p.P269= | Silent (SNP) | VAF 56/250 reads (22%) | called by muse, mutect2, varscan2
- RALYL | c.597C>A p.I199= | Silent (SNP) | VAF 49/169 reads (29%) | catalogued as COSV72821885; called by muse, mutect2, varscan2
- TTC32 | c.453T>C p.Y151= | Silent (SNP) | VAF 48/100 reads (48%) | catalogued as rs1483644996; called by muse, mutect2, varscan2
- ZNF541 | c.3462C>T p.L1154= | Silent (SNP) | VAF 54/178 reads (30%) | catalogued as rs370875978; called by muse, mutect2, varscan2
- ALDH1A2 | c.*51C>G | 3'UTR (SNP) | VAF 26/358 reads (7%) | called by muse, mutect2
- AP003393.1 | n.515-707G>C | Intron (SNP) | VAF 138/560 reads (25%) | catalogued as COSV58228690; called by muse, mutect2, varscan2
- C20orf197 | n.400C>G | RNA (SNP) | VAF 29/145 reads (20%) | called by muse, mutect2, varscan2
- CARTPT | c.*7G>A | 3'UTR (SNP) | VAF 78/248 reads (31%) | catalogued as rs1410781715; called by mutect2, varscan2
- CYYR1 | c.-7G>A | 5'UTR (SNP) | VAF 55/243 reads (23%) | called by muse, mutect2, varscan2
- DENND3 | c.3396+111G>A | Intron (SNP) | VAF 148/497 reads (30%) | catalogued as rs768073187; called by muse, mutect2, varscan2
- GALNT13 | c.1531-3748T>A | Intron (SNP) | VAF 20/96 reads (21%) | catalogued as COSV101221852; called by muse, mutect2, varscan2
- NBPF22P | n.300C>T | RNA (SNP) | VAF 67/268 reads (25%) | catalogued as rs1271946503; called by muse, mutect2, varscan2
- NLRP3 | c.-36G>A | 5'UTR (SNP) | VAF 146/315 reads (46%) | catalogued as rs755242195; called by muse, mutect2, varscan2
- PLB1 | c.1281-12C>T | Intron (SNP) | VAF 36/162 reads (22%) | called by muse, mutect2, varscan2
- RFX4 | c.44-7469C>T | Intron (SNP) | VAF 44/183 reads (24%) | catalogued as COSV100774228; called by muse, mutect2, varscan2
- RPS17 | c.3+101C>T | Intron (SNP) | VAF 74/245 reads (30%) | called by muse, mutect2, varscan2
- TRDN | c.484+1078T>A | Intron (SNP) | VAF 54/192 reads (28%) | called by muse, mutect2, varscan2
- TSPY8 | c.-38G>A | 5'UTR (SNP) | VAF 29/138 reads (21%) | called by muse, mutect2, varscan2
- TUBB8P7 | n.894+197G>A | Intron (SNP) | VAF 94/330 reads (28%) | catalogued as rs925267222; called by muse, mutect2
- ZNF280D | c.2213+13T>C | Intron (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
